Gene-level copy-number profile of tumor specimen TCGA-F7-A61W-01A from TCGA case TCGA-F7-A61W, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 51.7 years (18,879 days).
Specimen TCGA-F7-A61W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.d49c8a52-3afc-447d-94f0-6c6b3156a061.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-F7-A61W-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b7d593d3-01b7-43a4-943a-a57655739a60

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 13,274; copy number 2: 44,307; copy number 3: 2,147; copy number 5: 3; copy number 6: 50; copy number 9: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-F7-A61W-01A-11D-A28Q-01): tumor purity 0.82, ploidy 1.85, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:174,756,850–174,922,440, 5 genes: BANF1P4, NDUFAF4P4, Z99127.2, RABGAP1L-IT1, Z99127.1.
- chr2:45,651,345–46,187,990, 1 gene (within-gene range 0–2): PRKCE.
- chr2:46,003,942–46,004,309, 1 gene: RPL26P15.
- chr5:94,152,966–94,618,597, 4 genes (within-gene range 0–1): KIAA0825, MTND5P12, MTND6P3, MTCYBP35.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–1): AL359922.1.
- chr9:21,929,457–22,128,103, 9 genes (within-gene range 0–1): ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr9:122,940,833–123,104,866, 1 gene (within-gene range 0–2): RABGAP1.
- chr9:123,029,373–123,115,477, 4 genes: AC007066.1, GPR21, AL365338.1, MIR600HG.
- chr9:123,111,546–123,111,643, 1 gene: MIR600.
- chr18:65,917,782–66,946,222, 4 genes: AC023394.1, PRPF19P1, CDH19, RNU6-1037P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 57 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:25,529,177–28,600,275, 34 genes, copy number 5–6 (within-gene range 2–6): AC105290.1, RNU7-126P, AC092436.1, SLC34A2, RPS29P11, AC092436.2, MTND4P9, MTND4LP22, MTND3P5, MTCO3P44, SEL1L3, AC092436.3, SMIM20, AC133961.1, LINC02357, AC097714.1, RBPJ, CCKAR, TBC1D19, AC107390.1, STIM2, STIM2-AS1, PIMREGP4, AC024132.2, AC024132.1, LINC02261, Y_RNA, AC024132.3, IGBP1P5, AC007106.2, AC007106.1, AC093791.2, AC093791.1, AC097480.1.
- chr18:24,162,045–24,397,880, 1 gene, copy number 6 (within-gene range 2–6): OSBPL1A.
- chr18:24,321,686–25,352,190, 22 genes, copy number 6–9: MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.4, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1.

Autosomal genes at a single copy (total copy number 1): 10,853. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
